Gene-level copy-number profile of tumor specimen TCGA-NC-A5HT-01A from TCGA case TCGA-NC-A5HT, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.7 years (25,466 days).
Specimen TCGA-NC-A5HT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1ea78f3e-0767-4757-a538-4f159301fc73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/98e72cc5-71d6-4540-ba48-7c41d09c617e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 14,663; copy number 2: 35,115; copy number 3: 6,786; copy number 4: 2,652; copy number 5: 23; copy number 6: 153; copy number 7: 411; copy number 8: 3; copy number 15: 4; copy number 32: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HT-01A-11D-A26L-01): tumor purity 0.73, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 596 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,971,823–149,736,714, 73 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:150,150,538–175,810,548, 360 genes, copy number 6–32 (within-gene range 2–32) (broad region; genes not listed).
- chr8:41,261,962–41,650,817, 16 genes, copy number 5: SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3.
- chr8:41,660,441–41,665,566, 3 genes, copy number 5: MIR486-1, MIR486-2, AC113133.1.
- chr17:78,897,264–82,098,294, 144 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,283. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
